Gene-level copy-number profile of tumor specimen TCGA-IG-A50L-01A from TCGA case TCGA-IG-A50L, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 58.1 years (21,214 days).
Specimen TCGA-IG-A50L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.06a03007-a6fa-4a33-8c35-233ee9f896f8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IG-A50L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c8bae5f0-5a92-433c-b9a0-5d3b55b4a71a

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 515; copy number 2: 16,818; copy number 3: 21,209; copy number 4: 13,582; copy number 5: 3,761; copy number 6: 3,114; copy number 7: 128; copy number 8: 476; copy number 9: 32; copy number 11: 109; copy number 25: 62.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IG-A50L-01A-11D-A25X-01): tumor purity 0.57, ploidy 1.68, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 807 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–1,309,377, 48 genes, copy number 8: AC113430.1, PLEKHG4B, Y_RNA, LRRC14B, AC021087.4, CCDC127, AC021087.3, SDHA, AC021087.5, AC021087.1, PDCD6, PDCD6-AHRR, AC021087.2, AHRR, AC010442.1, AC010442.2, EXOC3-AS1, EXOC3, PP7080, SLC9A3, SLC9A3-AS1, AC106772.2, MIR4456, AC106772.1, CEP72, TPPP, AC026740.1, ZDHHC11B, BRD9P2, AC026740.2, ZDHHC11, SPCS2P3, BRD9, TRIP13, AC122719.3, AC122719.1, AC122719.2, AC116351.1, AC116351.2, NKD2, SLC12A7, MIR4635, CTD-3080P12.3, SLC6A19, SLC6A18, AC114291.1, TERT, MIR4457.
- chr7:41,667,168–56,467,771, 262 genes, copy number 7–11 (broad region; genes not listed).
- chr8:124,811,042–128,564,679, 62 genes, copy number 25 (broad region; genes not listed).
- chr9:117,462,294–117,466,260, 1 gene, copy number 8 (within-gene range 6–8): AL445644.1.
- chr10:43,900,874–44,415,153, 9 genes, copy number 8: LINC02659, LINC00841, AL139237.1, AL137026.2, AL137026.1, LINC02881, AL137026.3, CXCL12, RPL9P21.
- chr11:58,834,065–59,392,292, 26 genes, copy number 9: GLYATL2, GLYATL1P2, GLYATL1, AP001652.1, AP001636.3, AP001636.2, GLYATL1P1, AP001636.1, GLYATL1P4, GLYATL1B, FAM111B, FAM111A-DT, AP001258.1, FAM111A, DTX4, MPEG1, RN7SL42P, WARS1P1, SLC25A47P1, AP002358.1, AP002358.2, RN7SL435P, OR5AN2P, OR5BR1P, OR5AN1, OR5BB1P.
- chr18:47,390–15,330,282, 376 genes, copy number 8 (broad region; genes not listed).
- chr19:10,960,932–11,079,426, 1 gene, copy number 11 (within-gene range 3–11): SMARCA4.
- chr19:11,033,727–11,419,328, 22 genes, copy number 11: AC006127.1, LDLR, MIR6886, SPC24, KANK2, DOCK6, AC011472.1, AC011472.5, AC011472.4, ANGPTL8, TSPAN16, AC011472.2, RAB3D, AC011472.3, TMEM205, CCDC159, PLPPR2, AC024575.1, SWSAP1, EPOR, RGL3, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 21. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
